Somatic mutation profile of tumor specimen TCGA-EM-A2CO-01A (aliquot TCGA-EM-A2CO-01A-11D-A19J-08) from TCGA case TCGA-EM-A2CO, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 77.8 years (28,424 days).
Specimen TCGA-EM-A2CO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 58603d31-ae5b-4646-bdbd-104d6b120117.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A2CO-10A (Blood Derived Normal), aliquot TCGA-EM-A2CO-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa0eef69-09d3-493b-a427-4256bb9e8f1b

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 9, Silent 3, Frame Shift Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM83F | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV61001041; called by muse, mutect2
- HELLS | c.2466A>G p.I822M | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as COSV53301993; called by muse, mutect2, varscan2
- KASH5 | c.1516G>A p.G506S | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as rs1340167234, COSV71358541; called by muse, mutect2, varscan2
- PCID2 | c.84G>T p.L28F | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV55815513; called by muse, mutect2
- PIH1D2 | c.188A>G p.E63G | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV54776861; called by muse, mutect2, varscan2
- RIMS3 | c.446G>A p.R149Q | Missense Mutation (SNP) | VAF 89/167 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); catalogued as rs1363860302, COSV65505630; called by muse, mutect2, varscan2
- RTP1 | c.287G>T p.W96L | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0.114); catalogued as COSV56619755; called by muse, mutect2, varscan2
- SLC25A45 | c.673A>G p.I225V | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.79); PolyPhen benign (0.075); catalogued as rs745508952, COSV53685163; called by muse, mutect2, varscan2
- VCAM1 | c.561G>T p.E187D | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV54122887; called by muse, mutect2, varscan2
- ARHGAP29 | c.2644_2647del p.S882Rfs*17 | Frame Shift Del (DEL) | VAF 20/97 reads (21%) | called by mutect2, pindel, varscan2
- WIPF2 | c.545del p.P182Qfs*56 | Frame Shift Del (DEL) | VAF 7/62 reads (11%) | called by mutect2, pindel, varscan2
- ZNF407 | c.5918dup p.L1973Ffs*26 | Frame Shift Ins (INS) | VAF 5/10 reads (50%) | called by mutect2, varscan2
- ANKEF1 | c.372G>A p.P124= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as rs1249948656, COSV65694063; called by muse, mutect2, varscan2
- NEB | c.16218C>T p.Y5406= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV51467497; called by muse, mutect2
- TSNAX | c.453A>G p.Q151= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs769983684, COSV64147498; called by muse, mutect2, varscan2
